Gene-level copy-number profile of tumor specimen TCGA-XE-AAO0-01A from TCGA case TCGA-XE-AAO0, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 29.8 years (10,884 days).
Specimen TCGA-XE-AAO0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ab5b115f-b995-4109-9f90-40ca67d5e864.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-XE-AAO0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/f236851d-fdaf-4366-9bb1-abc44ccb762c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3,906; copy number 2: 19,708; copy number 3: 27,662; copy number 4: 6,790; copy number 5: 849.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,394. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
